Surgical pathology report (de-identified scan), TCGA case TCGA-UB-A7MD, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UCSF, specimen TCGA-UB-A7MD-01A (Primary Tumor).

[page 1 of 5]
Results

Surgical Pathology

(enter 1 per line): 1. bile duct-frozen (Order

Result Information

Status (Last updated Date/Time)

Accession #

Result Impression

SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Sex: Male

Soc. Sec. #:

Accession #:

Visit #:

Service

Receive

Locatio

Client:

Physici

CLF ICD O-3
Carcinoma, hepatocellular 8170/3
path
Carcinoma, hepatocellular 8175/3
pleomorphic
Site: Liver C22.0
9/26/13

FINAL PATHOLOGIC DIAGNOSIS

- A. Lymph node, "bile duct," biopsy: No tumor in one lymph node (0/1).
- B. Liver, "tumor margin," biopsy: Cirrhotic liver, no tumor.
- C. Gallbladder, cholecystectomy:
1. Cholelithiasis and mild cholesterosis.
2. No tumor in one lymph node (0/1).
- D. Liver, partial hepatectomy:
1. Hepatocellular carcinoma, moderately to poorly differentiated, 5.3 cm, margins negative; see comment.
2. Micronodular cirrhosis consistent with clinical history of hepatitis C virus and alcoholic liver disease.

COMMENT:

Liver Tumor, Including Intrahepatic Bile Duct, Synoptic Comment

- Tumor type: Hepatocellular carcinoma, moderately differentiated trabecular pattern, with foci of poorly differentiated pleomorphic subtype (slide D2).

[page 2 of 5]
- [REDACTED]
- Histologic grade: Moderately to poorly differentiated.
- Tumor size (maximum diameter of largest lesion): 5.3 cm.
- Tumor necrosis: Less than 30%.
- Multifocality (more than one tumor separated by nontumorous liver parenchyma): Absent.
- Estimated total tumor diameter of all HCC foci: 5.3 cm.
- Vascular invasion: Small vessel invasion, slide D3. No large vessel invasion.
- Hepatic capsule: No tumor in capsule.
- Local extension of tumor: Confined to liver.
- Hepatic surgical margins: Negative; tumor is 0.8 cm from medial margin, grossly.
- Non-neoplastic liver: Micronodular cirrhosis (confirmed by trichrome stain).
- Steatosis: Mild.
- Iron stain (in cirrhotic liver), scale 0-4+: 0.
- Hepatocellular nodules (in cirrhotic liver): None.
- Lymph node status: Negative; total number of nodes examined: 2 (0/2).
- AJCC Stage: pT1Nx.

has reviewed slides D3 and D5 and agrees with the presence of small vessel invasion in the absence of large vessel involvement.

Specimen(s) Received

A: Bile duct (FS)
B: Tumor margin (FS)
C: Gallbladder
D: Liver, partial resection

Intraoperative Diagnosis

FS1 (A) Bile duct, lymph node, biopsy: No tumor, no carcinoma. (Dr.

FS2 (B) Liver, biopsy: Cirrhotic liver with focal cautery.

IOC1 (D) Right lobe liver, wedge resection: Margins grossly clear, lesion 0.8 cm from the medial margin.

Clinical History

OR Room and Phone # (frozen specimen : intraoperative consults only)

Collection Time

The patient is a -year-old man with biopsy-proven hepatocellular carcinoma (not reviewed at of the right liver lobe. Per Dr. the patient also has hepatitis C virus and alcoholic liver disease. Recent imaging reveals a 5 x 4 cm segment 5/6 hepatic hypervascular mass. The patient now undergoes open partial right hepatectomy and cholecystectomy.

Gross Description

The case is received in four parts, labeled with the patient's name and

[REDACTED]

[page 3 of 5]
[REDACTED]

medical record number.

Part A is received fresh and additionally labeled "bile duct," and consists of a single, soft, red-tan, ovoid unoriented lymph node (2 x 1.3 x 1 cm). The specimen is trisected, revealing soft red-tan parenchyma without discrete mass or lesion. One-third of the specimen is submitted for frozen section diagnosis 1, with the frozen section remnant subsequently submitted in cassette A1. The remaining fresh lymph node is submitted in cassette A2.

Part B is received fresh and additionally labeled "margin-FS," and consists of one, rubbery, rectangular fragment of deep red to brown firm soft tissue (1 x 0.9 x 0.3 cm). The specimen is entirely frozen for frozen section diagnosis 2 with the cauterized surface embedded down with the frozen section remnant submitted in cassette B1.

Part C is received fresh and additionally labeled "gallbladder," and consists of a single unoriented, intact gallbladder (8 cm x 2.5-3.8 cm body-fundus, 0.1 cm wall thickness). The gallbladder is filled with yellow-brown, viscid fluid and a 1.8 cm, yellow-brown, crystalline stone. The mucosa is red-tan and granular. The hepatic surface is pink-tan and roughened with brown-tan cautery artifact. A single pink-tan lymph node (0.7 cm in greatest dimension) is identified in the scant attached yellow adipose tissue. The cystic duct margin is inked blue, and submitted together with representative sections of the fundus, body and lymph node.

Part D is received fresh and additionally labeled "right liver lobe," and consists of a portion of liver (6.5 cm from right to left x 5 cm from anterior to posterior x 7 cm from superior to inferior).

GROSS ABNORMALITIES: There is a 5.3 x 4.2 x 4 cm, yellow-tan, well-circumscribed but unencapsulated mass with yellow-tan to white, lobular parenchyma. The mass is located 0.8 cm from the closest approach to the medial margin, 1.1 cm from the closest approach to the inferior and superior margins, 1.4 cm from the closest approach to the lateral margin, and 2.4 cm from the closest approach to the deep margin. The mass approaches the hepatic capsule to within 0.1 cm. The surrounding uninvolved hepatic parenchyma is tan-red and micronodular (less than 0.1 cm to 0.1 cm). No lymph nodes are identified.

ORIENTED BY: Surgeon's sutures: Long - superior, short - medial.

INKING:

- Superior: Blue.
- Inferior: Green.
- Posterior: Black.

CASSETTES: Representative sections are submitted in cassettes as follows:

- D1: Mass with closest approach to superior margin.
- D2: Mass with closest approach to inferior margin.
- D3-D5: Representative sections of mass.
- D6: Representative section of liver, away from mass, medial.
- D7: Representative section of liver, away from mass, lateral.
- D8: Mass with closest approach to deep margin.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations and preliminary

[REDACTED]

[page 4 of 5]
[REDACTED]

interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

/Pathologist
Electronically signed out

Pathology PDF Report

Show images for Surgical Pathology (enter 1 per line): 1. bile duct-frozen

Authorizing Provider Information

Name: _____

Phone: _____

Signed by _____

Signed

Phone

Pager

Result History

SURGICAL PATHOLOGY

Surgical Pathology

(enter 1 per line): 1. bile duct-frozen

This is NOT a Requisition. Requisition hyperlink below.

Surgical Pathology

(enter 1 per line): 1. bile duct-frozen

Pathology and Cytology

Show images for Surgical Pathology

(enter 1 per line): 1. bile duct-frozen

Order Information

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Release Information

Released On

Released By

Order Details

Frequency
Once

Duration
1 occurrence

Priority
STAT

Order Class
Unit Collect

Order Questions

Question

Answer

Comment

Specimen

(enter 1 per line)

1. bile duct-frozen

Lab Collection and Receipt Information

[REDACTED]

[page 5 of 5]
Collect Date

Collect Time

Collected By

Lab Receipt Date

Lab Receipt Time

Collection Information

Resulting Agency

Order Provider Info

Ordering User

Office
phone

Pager/beeper E-mail

Authorizing Provider

Billing Provider

Electronically Signed By:

Electronically Authorized By

Electronically Ordered By

Acknowledgement Info

For

At

Acknowledged By

Acknowledged On

Order Status for: SURGICAL PATHOLOGY

Parent Status: Completed

Child Orders

(This order does not yet have any children)

Order Requisition

Surgical Pathology (enter 1 per line): 1. bile duct-frozen

H-PAA Discrepancy		✓

Source: NCI Genomic Data Commons file 7c4cc74f-803b-4d22-922a-6c319830d15c (TCGA-UB-A7MD.DF3145A4-6311-4DCD-914F-3B3AABE4DAE7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).